Gene-level copy-number profile of tumor specimen C3N-01200-01 from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 557e399a-bdc1-4531-b15a-c48e5562cc2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01200-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/162230c1-2778-4297-a630-0abf04cac4c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 12,000; copy number 2: 40,233; copy number 3: 6,104; copy number 4: 2; copy number 5: 1; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,642,494, 10 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr10:87,751,512–88,259,372, 10 genes: ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr17:7,549,058–7,929,803, 33 genes (within-gene range 0–1): TNFSF12, TNFSF12-TNFSF13, AC016876.3, TNFSF13, SENP3, SENP3-EIF4A1, EIF4A1, AC016876.2, SNORA48, SNORD10, SNORA67, CD68, AC016876.1, MPDU1, SOX15, FXR2, SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3, DNAH2, RPL29P2, KDM6B, TMEM88, NAA38, CYB5D1, AC104581.4, CHD3, SCARNA21, RNF227, KCNAB3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:126,496,279–126,498,604, 1 gene, copy number 5 (within-gene range 2–5): AC093535.2.
- chr10:133,778,246–133,778,699, 2 genes, copy number 8: RPL23AP60, BX322534.1.

Autosomal genes at a single copy (total copy number 1): 11,974. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
